Somatic mutation profile of tumor specimen TARGET-30-PASTCN-01A (aliquot TARGET-30-PASTCN-01A-01D) from TARGET case TARGET-30-PASTCN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Overlapping lesion of retroperitoneum and peritoneum; Age at diagnosis: 5.2 years (1,900 days).
Specimen TARGET-30-PASTCN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ac814bf-4444-46b4-8c80-77e803f642fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASTCN-10A (Blood Derived Normal), aliquot TARGET-30-PASTCN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df6a531b-e57f-4a2d-83c0-2affc314c49d

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.1676C>G p.T559S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV52529733; called by muse, mutect2, varscan2
- AKAP4 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62073864; called by mutect2, varscan2
- ASIC4 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61731144; called by muse, mutect2, varscan2
- CHMP4C | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926334; called by muse, mutect2, varscan2
- GLI4 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV60681559; called by muse, mutect2, varscan2
- SEC62 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs1445464288, COSV61260797; called by muse, mutect2, varscan2
- SLC22A2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV65265784; called by muse, mutect2, varscan2
- TEKT4 | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV54623318; called by muse, mutect2, varscan2
- TET1 | c.918A>G p.I306M | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV65382512; called by muse, mutect2, varscan2
- ANO1 | c.1292dup p.M432Dfs*13 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- HYKK | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP20 | c.1731C>T p.C577= | Silent (SNP) | VAF 20/23 reads (87%) | catalogued as COSV52807401; called by muse, mutect2, varscan2
- DCP1A | c.375G>T p.V125= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV53687588; called by muse, mutect2, varscan2
- MYO1F | c.2010G>C p.G670= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100597010, COSV57792410; called by muse, varscan2
- PDGFC | c.252A>G p.V84= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs779821287, COSV56845709; called by muse, mutect2, varscan2
- PGM5 | c.429T>A p.P143= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV67163009; called by muse, mutect2, varscan2
